MMRF case MMRF_2300 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/6dae99a7-88ab-4477-8228-efb00dd3bb8f

Demographics
Sex at birth: male; Race: white; Ethnicity: hispanic or latino; Age at index: 80 years; Vital status: Dead; Days to death: 66 days; Cause of death: Not Cancer Related.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 80.3 years (29,340 days); ISS stage: III; Days to last known disease status: 66 days; Days to last follow up: 66 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 14 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 3 days; Days to treatment end: 66 days.
   Treatment given: Therapeutic agents: Prednisone; Regimen or line of therapy: First line of therapy; Days to treatment start: 24 days; Days to treatment end: 66 days.
   Treatment given: Therapeutic agents: Cyclophosphamide; Regimen or line of therapy: First line of therapy; Days to treatment start: 42 days; Days to treatment end: 66 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -1 (ECOG 2): M Protein 6.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 201 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.1 mg/dL; Immunoglobulin G 76.8 g/L; Immunoglobulin A 0.05 g/L; Immunoglobulin M 0.067 g/L; Beta 2 Microglobulin 7.69 µg/mL; Lactate Dehydrogenase 5.77 µkat/L; Hemoglobin 6.51 mmol/L; Leukocytes 11.9 ×10⁹/L; Absolute Neutrophil 5.64 ×10⁹/L; Platelets 47 ×10⁹/L; Creatinine 186 µmol/L; Calcium 2.15 mmol/L; Albumin 25.9 g/L; Total Protein 13 g/dL; Glucose 5.94 mmol/L; C-Reactive Protein 0.19 mg/dL.
- Day 66 (ECOG 5): M Protein 4.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 202 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.144 mg/dL; Immunoglobulin G 53.7 g/L; Immunoglobulin A 0.05 g/L; Immunoglobulin M 0.08 g/L; Beta 2 Microglobulin 30.8 µg/mL; Lactate Dehydrogenase 7.33 µkat/L; Hemoglobin 6.39 mmol/L; Leukocytes 8.98 ×10⁹/L; Absolute Neutrophil 7.06 ×10⁹/L; Platelets 149 ×10⁹/L; Creatinine 265 µmol/L; Calcium 1.98 mmol/L; Albumin 28 g/L; Total Protein 8.9 g/dL; Glucose 6.22 mmol/L.

Other clinical attributes
- Day -1: Weight: 87 kg; Height: 165 cm.

Biospecimens (2 samples)
- Sample MMRF_2300_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -1 day.
- Sample MMRF_2300_1_PB_WBC: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -1 day.
